Somatic mutation profile of tumor specimen TCGA-A4-7996-01A (aliquot TCGA-A4-7996-01A-11D-2201-08) from TCGA case TCGA-A4-7996, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.8 years (22,559 days).
Specimen TCGA-A4-7996-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2863705c-3aef-4eb9-9820-774113677b93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-7996-10A (Blood Derived Normal), aliquot TCGA-A4-7996-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac118d3d-f3b0-49fd-a8b1-49b0dfab6aed

The open-access MAF lists 86 somatic variants for this specimen: 67 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 46, Silent 19, Frame Shift Del 13, Frame Shift Ins 3, Nonsense Mutation 2, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC2 | c.4275del p.L1426Yfs*5 | Frame Shift Del (DEL) | VAF 83/173 reads (48%) | catalogued as COSV64988502; called by pindel, varscan2
- AC093827.5 | c.220T>A p.S74T | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV55744977; called by muse, mutect2, varscan2
- AGMAT | c.442A>T p.I148F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV65435689; called by muse, mutect2, varscan2
- AL441992.2 | c.331T>A p.W111R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV56912799; called by muse, mutect2, varscan2
- ANO1 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1347877999, COSV60282247, COSV60285275; called by muse, mutect2, varscan2
- ARVCF | c.1684G>C p.D562H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54265504; called by muse, mutect2, varscan2
- CCR3 | c.691A>G p.S231G | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV62461798; called by muse, mutect2, varscan2
- CLTB | c.23_25del p.F8del | In Frame Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs752241940; called by pindel, varscan2
- DOCK4 | c.1157C>T p.T386I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV70316220, COSV70324556; called by muse, mutect2, varscan2
- DYNC1H1 | c.10750A>G p.N3584D | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as rs1332342693, COSV64135013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFNA1 | c.353A>G p.K118R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as COSV57596378; called by muse, mutect2, varscan2
- F12 | c.865T>C p.Y289H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); catalogued as COSV53690312, COSV53691327; called by muse, mutect2, varscan2
- FHDC1 | c.2416G>A p.G806S | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.162); catalogued as rs751969879, COSV52598412; called by muse, mutect2, varscan2
- GAREM1 | c.1304T>C p.F435S | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.03); catalogued as COSV52506913; called by muse, mutect2, varscan2
- GIGYF2 | c.1625A>G p.Q542R | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766027588, COSV65247414; called by muse, mutect2, varscan2
- GNAI2 | c.719A>C p.E240A | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as COSV56493059; called by muse, mutect2, varscan2
- HRC | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53255567, COSV53255968; called by muse, varscan2
- IL1RL2 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as COSV51813771; called by muse, mutect2, varscan2
- KIF13B | c.2646G>C p.Q882H | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.854); catalogued as COSV72954283; called by muse, mutect2, varscan2
- LRPPRC | c.3208T>C p.Y1070H | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53235380; called by muse, mutect2, varscan2
- MOCS3 | c.824T>G p.L275W | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54865848; called by muse, mutect2, varscan2
- MTHFD2 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1398564713, COSV51201096; called by muse, mutect2, varscan2
- NBEAL1 | c.6244A>T p.N2082Y | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV68915723; called by muse, mutect2, varscan2
- NTRK3 | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as COSV58111532, COSV58113633; called by muse, mutect2, varscan2
- OR52K1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs768055536, COSV56903202; called by muse, mutect2, varscan2
- PAPSS2 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV63262828; called by muse, mutect2, varscan2
- PATJ | c.3172C>T p.P1058S | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57157568; called by muse, mutect2, varscan2
- PCDHA11 | c.1409G>C p.G470A | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554164342, COSV100247699; called by muse, mutect2
- PKP3 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100520990; called by muse, mutect2
- PLK4 | c.2007C>A p.N669K | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.372); catalogued as COSV54636704, COSV99584689; called by muse, mutect2, varscan2
- PRSS22 | c.545G>A p.S182N | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.988); catalogued as COSV50721204; called by muse, mutect2, varscan2
- PTCHD3 | c.1819T>C p.F607L | Missense Mutation (SNP) | VAF 60/90 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71256398; called by muse, mutect2, varscan2
- RERE | c.460T>A p.S154T | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT tolerated, low confidence (0.38); PolyPhen probably damaging (0.95); catalogued as COSV61938507; called by muse, mutect2, varscan2
- RHCG | c.493A>G p.N165D | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV51515063; called by muse, mutect2, varscan2
- SEMA4F | c.244C>G p.R82G | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140925977, COSV60282287; called by muse, mutect2, varscan2
- SKIV2L | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 125/423 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV64810615; called by muse, mutect2, varscan2
- SLC12A7 | c.2063A>C p.K688T | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV53755271; called by muse, mutect2, varscan2
- SLC24A3 | c.1719+1G>C p.X573_splice | Splice Site (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100039528, COSV100043605; called by muse, varscan2
- SLC25A45 | c.685A>G p.M229V | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs778973970, COSV53683477; called by muse, mutect2, varscan2
- SLC5A9 | c.2002C>T p.L668F | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV52582471; called by muse, mutect2, varscan2
- SSH2 | c.1182G>T p.M394I | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52168031; called by muse, mutect2, varscan2
- TLN1 | c.6822G>T p.K2274N | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59205095; called by muse, mutect2, varscan2
- TMEM120B | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763021435, COSV61182755, COSV61184502; called by muse, mutect2, varscan2
- TNFRSF1B | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs1446742239, COSV66163650; called by muse, mutect2, varscan2
- VN1R2 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 31/130 reads (24%) | catalogued as rs374706531, COSV59037483, COSV59038566; called by muse, mutect2, varscan2
- WAPL | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 107/151 reads (71%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.027); catalogued as COSV53933202; called by muse, mutect2, varscan2
- ZC3H12C | c.317T>C p.I106T | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV53707155; called by muse, mutect2, varscan2
- ZNF200 | c.952del p.R318Vfs*14 | Frame Shift Del (DEL) | VAF 96/239 reads (40%) | catalogued as rs771463261; called by mutect2, pindel, varscan2
- ZNF516 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101487381, COSV71586782; called by muse, mutect2, varscan2
- ZXDC | c.239A>G p.E80G | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV60446015; called by muse, mutect2, varscan2
- ZYG11B | c.2105A>G p.K702R | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV53750896; called by muse, mutect2, varscan2
- AGPAT1 | c.6_13del p.L3Rfs*156 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, varscan2
- ANKZF1 | c.1466del p.P489Lfs*22 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- BAIAP3 | c.3252_3254+4del p.X1084_splice | Splice Site (DEL) | VAF 54/114 reads (47%) | called by mutect2, pindel, varscan2
- COL5A2 | c.4476_4477dup p.I1493Kfs*31 | Frame Shift Ins (INS) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- CYP21A2 | c.799_803del p.Q267Efs*27 | Frame Shift Del (DEL) | VAF 58/279 reads (21%) | called by mutect2, pindel*, varscan2
- DENND5A | c.2461del p.L821Cfs*40 | Frame Shift Del (DEL) | VAF 50/184 reads (27%) | called by mutect2, pindel, varscan2
- MAT2B | c.275dup p.H92Qfs*22 | Frame Shift Ins (INS) | VAF 31/101 reads (31%) | called by mutect2, pindel, varscan2
- MMP21 | c.1598del p.K533Rfs*35 | Frame Shift Del (DEL) | VAF 55/126 reads (44%) | called by mutect2, pindel, varscan2
- MPP6 | c.1453_1465del p.D485Qfs*18 | Frame Shift Del (DEL) | VAF 54/146 reads (37%) | called by mutect2, pindel, varscan2
- NCOA4 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 63/96 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- PKDREJ | c.3500del p.P1167Lfs*8 | Frame Shift Del (DEL) | VAF 43/203 reads (21%) | called by mutect2, pindel, varscan2
- PTEN | c.674_675del p.Y225Ffs*17 | Frame Shift Del (DEL) | VAF 70/164 reads (43%) | called by pindel, varscan2
- RLIM | c.8del p.N3Tfs*34 | Frame Shift Del (DEL) | VAF 28/73 reads (38%) | called by mutect2, pindel, varscan2
- TRAF4 | c.156dup p.K53Qfs*4 | Frame Shift Ins (INS) | VAF 70/164 reads (43%) | called by mutect2, pindel, varscan2
- TRAPPC9 | c.709_710del p.N237* | Frame Shift Del (DEL) | VAF 58/158 reads (37%) | called by mutect2, pindel, varscan2
- ZMIZ2 | c.2702del p.G901Afs*73 | Frame Shift Del (DEL) | VAF 23/120 reads (19%) | called by mutect2, pindel, varscan2
- ACAN | c.2646C>T p.F882= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV61357525; called by muse, mutect2, varscan2
- BRD4 | c.3396G>A p.E1132= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV54583414; called by muse, mutect2, varscan2
- CD209 | c.438C>T p.I146= | Silent (SNP) | VAF 71/220 reads (32%) | catalogued as COSV52650813; called by muse, varscan2
- DRD2 | c.30T>C p.D10= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as rs767338366, COSV60755426; called by muse, mutect2, varscan2
- FCGBP | c.3237T>C p.H1079= | Silent (SNP) | VAF 41/153 reads (27%) | called by muse, mutect2, varscan2
- KCNN3 | c.753C>T p.S251= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV55213686; called by muse, mutect2, varscan2
- KCNV2 | c.540C>T p.R180= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV66055669; called by muse, mutect2, varscan2
- OLFML2A | c.1431C>T p.Y477= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV56582296; called by muse, mutect2, varscan2
- PCED1B | c.63G>T p.L21= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV71394981; called by muse, mutect2, varscan2
- PKHD1 | c.789T>C p.S263= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as CD163037, COSV61865076; called by muse, mutect2, varscan2
- PRKN | c.81G>A p.K27= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as rs1317512001, CD123190, COSV58208629; called by muse, mutect2, varscan2
- PRSS22 | c.546C>T p.S182= | Silent (SNP) | VAF 55/106 reads (52%) | catalogued as COSV50721191; called by muse, mutect2, varscan2
- PSMD14 | c.444T>C p.I148= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV68831922; called by muse, mutect2
- RB1CC1 | c.2382G>A p.L794= | Silent (SNP) | VAF 56/160 reads (35%) | catalogued as COSV50244045; called by muse, mutect2, varscan2
- RELA | c.1017T>C p.A339= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs752091115, COSV58014091; called by muse, mutect2, varscan2
- RELN | c.7683A>G p.L2561= | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as rs1318379055, COSV58990745; called by muse, mutect2
- TCHH | c.3414G>A p.R1138= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as rs1306345780, COSV64273576; called by muse, mutect2, varscan2
- USP24 | c.2175T>C p.Y725= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV53763506; called by muse, mutect2, varscan2
- WIPF2 | c.102G>A p.Q34= | Silent (SNP) | VAF 38/155 reads (25%) | catalogued as COSV60272797; called by muse, mutect2, varscan2
